TCGA case TCGA-3B-A9HT — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4b3c152f-a9ea-48cc-9189-f09078a92c48

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Tongue, NOS; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,637 days); Year of diagnosis: 2010; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2.1; Tumor length measurement: 3.3; Tumor width measurement: 2.6.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 4.
2. Subsequent primary of the liver (histology not recorded by GDC). Age at diagnosis: 55.6 years (20,307 days); Days to diagnosis: 670 days (1.8 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 2.6; Tumor width measurement: 1.5.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 1,474 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,665 days (4.6 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-3B-A9HT-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Site of primary tumor other: Tongue; Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Head and Neck - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 4.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Liver; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: Yes.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 51; Days from index date to pharmaceutical treatment ended: 103; Pharmaceutical therapy drug name: Cisplatinum; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment: Days from index date to radiation therapy started: 51; Days from index date to radiation therapy ended: 106; Radiation therapy type: External; Radiation total dose: 6600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 33; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,665 days; disease-specific survival: no event (censored), 1,665 days; disease-free interval: no event (censored), 1,665 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 670 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HT-01A-11D-A38Y-01): tumor purity 1, ploidy 3.06, whole-genome doublings 1.
